Somatic mutation profile of tumor specimen TCGA-04-1362-01A (aliquot TCGA-04-1362-01A-01W-0492-08) from TCGA case TCGA-04-1362, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 59.5 years (21,745 days).
Specimen TCGA-04-1362-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6b90507-cfe1-4863-ae9b-25f87f070023.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1362-10A (Blood Derived Normal), aliquot TCGA-04-1362-10A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/beaeec2f-5ecf-4313-8d5a-6374375f4acf

The open-access MAF lists 80 somatic variants for this specimen: 66 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 12, Nonsense Mutation 5, Splice Site 3, Frame Shift Del 3, Frame Shift Ins 2, In Frame Del 2, Intron 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.673-1G>A p.X225_splice | Splice Site (SNP) | VAF 138/174 reads (79%) | hotspot (GDC flag); catalogued as rs878854073, CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS3 | c.2206C>G p.P736A | Missense Mutation (SNP) | VAF 126/503 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs199518563, COSV54387086; called by muse, mutect2, varscan2
- ADCY5 | c.1073C>G p.S358C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); catalogued as COSV101518438; called by muse, mutect2, varscan2
- ARL15 | c.178G>T p.V60F | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as COSV72289193; called by muse, mutect2, varscan2
- CA9 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 128/309 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV65675119; called by muse, mutect2, varscan2
- CARS1 | c.802G>C p.V268L | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV53451516; called by muse, mutect2, varscan2
- CDKL4 | c.309C>G p.I103M | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV66508766; called by muse, mutect2, varscan2
- CLGN | c.1736C>T p.S579F | Missense Mutation (SNP) | VAF 36/222 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV57773610; called by muse, mutect2, varscan2
- CLU | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.761); catalogued as rs371872334; called by muse, mutect2, varscan2
- CNNM3 | c.1367A>G p.Y456C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as rs1460336084, COSV59708829; called by muse, mutect2, varscan2
- CPT1A | c.1820C>G p.S607C | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99681273; called by mutect2, varscan2
- CRB1 | c.2095C>T p.H699Y | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66329019; called by muse, mutect2, varscan2
- CRNN | c.657A>T p.R219S | Missense Mutation (SNP) | VAF 53/666 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.987); catalogued as COSV99664169; called by muse, mutect2
- DIAPH3 | c.2818C>T p.P940S (on ENST00000400324 / NM_001042517.2; = p.P677S on NM_030932.3) | Missense Mutation (SNP) | VAF 124/266 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.231); catalogued as rs201024887, COSV57366318; called by muse, mutect2, varscan2
- DNM1L | c.1674G>T p.K558N | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as COSV99846168; called by muse, mutect2, varscan2
- EBF2 | c.246G>T p.E82D | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.716); catalogued as COSV68776593; called by muse, mutect2, varscan2
- ELK1 | c.105G>C p.K35N | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55952230; called by muse, mutect2, varscan2
- ENPP3 | c.749G>A p.W250* | Nonsense Mutation (SNP) | VAF 100/235 reads (43%) | catalogued as COSV62953305; called by muse, mutect2, varscan2
- FAM47C | c.1930C>G p.P644A | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.076); catalogued as COSV63724537; called by muse, mutect2, varscan2
- FBXO40 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 473/870 reads (54%) | catalogued as COSV104402871, COSV57522496; called by muse, mutect2, varscan2
- GLS | c.1757C>G p.S586C | Missense Mutation (SNP) | VAF 259/591 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV57840473; called by muse, mutect2, varscan2
- GPR78 | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV66762626, COSV66763399; called by muse, mutect2, varscan2
- HEMGN | c.460G>T p.A154S | Missense Mutation (SNP) | VAF 106/560 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.274); catalogued as rs774200186, COSV52325561; called by muse, mutect2, varscan2
- HEPHL1 | c.3031A>T p.S1011C | Missense Mutation (SNP) | VAF 225/404 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59890064, COSV59890480; called by muse, mutect2, varscan2
- HERC1 | c.9287T>G p.L3096* | Nonsense Mutation (SNP) | VAF 32/53 reads (60%) | catalogued as COSV71246579; called by muse, mutect2, varscan2
- HIVEP2 | c.5077C>G p.L1693V | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50006640; called by muse, mutect2, varscan2
- HOXA2 | c.1072A>G p.S358G | Missense Mutation (SNP) | VAF 182/208 reads (88%) | SIFT tolerated (0.16); PolyPhen benign (0.114); catalogued as COSV56065495; called by muse, mutect2, varscan2
- IGHV1-18 | c.209T>A p.I70N | Missense Mutation (SNP) | VAF 187/469 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.3); catalogued as rs370565499; called by muse, mutect2, varscan2
- IGSF8 | c.479dup p.G161Rfs*18 | Frame Shift Ins (INS) | VAF 6/29 reads (21%) | catalogued as rs754902711; called by mutect2, varscan2
- IVL | c.305A>C p.E102A | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV64215753; called by muse, mutect2, varscan2
- JHY | c.436G>C p.A146P | Missense Mutation (SNP) | VAF 49/346 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as COSV56218323; called by muse, mutect2, varscan2
- LAMA2 | c.8548-1G>T p.X2850_splice | Splice Site (SNP) | VAF 54/65 reads (83%) | catalogued as COSV70341469; called by muse, mutect2, varscan2
- LRP2 | c.13623G>C p.V4541= | Splice Region (SNP) | VAF 146/692 reads (21%) | catalogued as COSV55544743; called by muse, mutect2, varscan2
- LRRC8A | c.130A>G p.T44A | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.062); catalogued as COSV99396672; called by muse, mutect2
- LRRIQ1 | c.2883G>C p.W961C | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.57); catalogued as COSV67827133; called by mutect2, varscan2
- MAGEB16 | c.303T>A p.D101E | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV67873669; called by muse, mutect2, varscan2
- MAPKBP1 | c.1001G>T p.R334L (on ENST00000456763 / NM_001128608.2; = p.R328L on NM_014994.3) | Missense Mutation (SNP) | VAF 50/546 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as COSV99529644; called by muse, mutect2
- MEST | c.367C>T p.Q123* | Nonsense Mutation (SNP) | VAF 20/117 reads (17%) | catalogued as COSV56227678; called by muse, mutect2, varscan2
- NR2F1 | c.1139T>G p.V380G | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59067807; called by muse, mutect2, varscan2
- OR5I1 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV56885814; called by muse, mutect2, varscan2
- OTOP2 | c.1642C>T p.R548C | Missense Mutation (SNP) | VAF 88/104 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201682015, COSV58880974; called by muse, mutect2, varscan2
- PKD1L1 | c.3911T>G p.L1304R | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56959921; called by muse, mutect2, varscan2
- PKD1L1 | c.2338C>A p.P780T | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56960202; called by muse, mutect2, varscan2
- PLXNA4 | c.4702G>T p.E1568* | Nonsense Mutation (SNP) | VAF 105/375 reads (28%) | catalogued as COSV58110848; called by muse, mutect2, varscan2
- PTPRZ1 | c.6532G>A p.D2178N | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); catalogued as COSV66432123; called by muse, mutect2, varscan2
- RBBP4 | c.245C>A p.A82D | Missense Mutation (SNP) | VAF 98/195 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100995703, COSV65132146; called by muse, mutect2, varscan2
- RIMS2 | c.3050A>T p.H1017L (on ENST00000666250 / NM_001348490.2; = p.H825L on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 496/1056 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV51660546; called by muse, mutect2, varscan2
- RTF1 | c.1987G>C p.D663H | Missense Mutation (SNP) | VAF 70/171 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67477813; called by muse, mutect2, varscan2
- SCN9A | c.1393A>T p.T465S | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as COSV57603190; called by muse, mutect2, varscan2
- SCRN2 | c.887A>T p.D296V | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV51635146; called by muse, mutect2, varscan2
- SEC11A | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs756279275, COSV51612248; called by muse, mutect2, varscan2
- SLC28A2 | c.191G>A p.S64N | Missense Mutation (SNP) | VAF 72/196 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV61663490; called by muse, mutect2, varscan2
- SON | c.5345C>T p.S1782F | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV51652878; called by muse, varscan2
- SOS1 | c.3691C>G p.L1231V | Missense Mutation (SNP) | VAF 116/275 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.952); catalogued as COSV67674200; called by muse, mutect2, varscan2
- SYDE2 | c.1264T>G p.S422A | Missense Mutation (SNP) | VAF 69/322 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV52314520; called by muse, mutect2, varscan2
- TENM2 | c.4000G>C p.E1334Q (on ENST00000518659 / NM_001122679.2; = p.E1095Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 57/386 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV69124720; called by muse, varscan2
- ZNF354A | c.1130C>A p.T377N | Missense Mutation (SNP) | VAF 37/303 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59982379; called by muse, mutect2, varscan2
- GUCD1 | c.623_628+1del p.X208_splice | Splice Site (DEL) | VAF 9/26 reads (35%) | called by mutect2, pindel*, varscan2
- HEPH | c.1541_1558del p.K514_W519del (on ENST00000343002; = p.K247_W252del on NM_014799.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 43/245 reads (18%) | called by mutect2, pindel, varscan2
- HLA-E | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.109); called by muse, mutect2
- JUP | c.2068_2073delinsT p.N690Sfs*5 | Frame Shift Del (DEL) | VAF 22/75 reads (29%) | called by pindel, varscan2*
- KRT1 | c.819_840del p.I274Rfs*5 | Frame Shift Del (DEL) | VAF 34/202 reads (17%) | called by mutect2, pindel
- NID2 | c.1295A>G p.E432G | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by mutect2, varscan2
- SECISBP2 | c.289_297del p.L97_S99del | In Frame Del (DEL) | VAF 104/1130 reads (9%) | called by mutect2, pindel
- TDP1 | c.341_344del p.K114Tfs*98 | Frame Shift Del (DEL) | VAF 45/86 reads (52%) | called by mutect2, pindel, varscan2
- ZNF217 | c.1360dup p.H454Pfs*4 | Frame Shift Ins (INS) | VAF 21/117 reads (18%) | called by mutect2, pindel, varscan2
- BEND3 | c.657G>A p.L219= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV64680235; called by muse, mutect2, varscan2
- BMPR2 | c.1773A>C p.R591= | Silent (SNP) | VAF 20/248 reads (8%) | catalogued as COSV101001537, COSV101001667, COSV65808773; called by muse, mutect2
- CHUK | c.789C>T p.S263= | Silent (SNP) | VAF 38/158 reads (24%) | catalogued as rs779091577, COSV64917395; called by muse, mutect2, varscan2
- FAM183A | c.156C>G p.P52= | Silent (SNP) | VAF 20/39 reads (51%) | catalogued as COSV100088250, COSV58921634; called by muse, mutect2, varscan2
- IGKV1D-43 | c.118A>C p.R40= | Silent (SNP) | VAF 400/759 reads (53%) | called by muse, mutect2, varscan2
- PC | c.2184A>G p.E728= | Silent (SNP) | VAF 21/88 reads (24%) | catalogued as COSV58992262; called by muse, mutect2, varscan2
- PZP | c.390C>T p.V130= | Silent (SNP) | VAF 186/454 reads (41%) | catalogued as COSV54356034; called by muse, mutect2, varscan2
- SVEP1 | c.8817A>C p.A2939= | Silent (SNP) | VAF 192/504 reads (38%) | catalogued as COSV52836720; called by muse, mutect2, varscan2
- TRAPPC8 | c.2737C>T p.L913= | Silent (SNP) | VAF 39/100 reads (39%) | catalogued as rs1037905725, COSV51968228; called by muse, mutect2, varscan2
- WWC3 | c.159C>T p.A53= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as COSV66501974; called by muse, mutect2, varscan2
- ZCCHC12 | c.447G>A p.V149= | Silent (SNP) | VAF 369/663 reads (56%) | catalogued as COSV59571099; called by muse, mutect2, varscan2
- ZNF229 | c.783A>G p.G261= | Silent (SNP) | VAF 51/107 reads (48%) | catalogued as COSV52160411; called by muse, mutect2, varscan2
- ETNK2 | c.519-744C>A | Intron (SNP) | VAF 39/90 reads (43%) | catalogued as COSV65820483; called by muse, mutect2, varscan2
- MIR513A1 | n.18C>A | RNA (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
